Surgical pathology report (de-identified scan), TCGA case TCGA-HD-A633, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-A633-01A (Primary Tumor).

[page 1 of 3]
Sex: Male
DOB: [REDACTED]

SPECIMEN INFORMATION

Collected:
Received:
Reported:

Accession #:
Acct / Reg

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Buccal margin, anterior to posterior:
Negative for dysplasia or malignancy.
Intraoperative consultation corroborated.
- B. Mental nerve; excision:
Peripheral nerve with no tumor identified.
Intraoperative consultation corroborated.
- C. Level 2B lymph node; neck dissection:
No metastatic carcinoma identified in ten lymph nodes (0/10).
- D. Left Level 2A; neck dissection:
No metastatic carcinoma identified in two lymph nodes (0/2).
- E. Left level 1; neck dissection:
No metastatic carcinoma identified in four lymph nodes (0/4).
Submandibular gland with no tumor identified.
- F. Left level 3; neck dissection:
No metastatic carcinoma identified in four lymph nodes (0/4).
- G. Left level 4; neck dissection:
No metastatic carcinoma identified in nineteen lymph nodes (0/19).
- H. Left lower mandibular tooth; extraction:
Tooth with no gross abnormalities.
- I. Retromolar regional superior margin, left:
Reactive squamous mucosa, negative for dysplasia or malignancy.
Intraoperative consultation corroborated.
- J. Floor of mouth:
Reactive squamous mucosa, negative for dysplasia or malignancy.
Intraoperative consultation corroborated.
- K. Inferior alveolar nerve; excision:
Peripheral nerve, no tumor identified within nerve.
Focal squamous cell carcinoma present in adjacent soft tissue.
Mandibular bone with no tumor identified.

L. Mandible; composite of resection:

Tumor Characteristics:

1. Histologic type: Invasive keratinizing squamous cell carcinoma.
2. Tumor histologic grade: Moderately differentiated.
3. Tumor site: Oral cavity, left mandible.
4. Maximal tumor diameter is 3.9 cm.
5. Depth of invasion: 0.8 cm.
6. Bone invasion: Present.
7. Lymphovascular space invasion: Not identified.
8. Perineural invasion: Not identified.
9. Carcinoma in situ: Present.

Surgical Margins:

1. Mucosal margins: Negative for tumor, see specimens I, J, and A for additionally submitted mucosal margins.

ICD-O-3

Carcinoma, squamous cell
keratinizing NOS 8071/3

Site: Oral Cavity NOS C06.9
path
mandibular gingiva C03.1

MD 5/10/13

[page 2 of 3]
SPECIMEN INFORMATION

DIAGNOSIS

2. Deep soft tissue margin: Negative for tumor by 0.2 cm.
3. Bone margins: Negative for tumor.
- Lymph Node Status:**
1. Total number of lymph nodes examined: 39, see specimens C-G.
2. Total number of lymph nodes containing metastatic carcinoma: 0 (0/39).
- Other:**
1. pTNM stage: pT4, NO.

Electronic Signature.

COMMENTS:

Histologic sections show an invasive squamous cell carcinoma arising within the mucosa overlying the mandible. The tumor invades into the mandible and is present in sections from the outer surface of the ramus. The mucosal margins and lymph nodes are negative for tumor.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Left mandibular cancer.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Buccal margin anterior to posterior
- B. Mental nerve - FS.
- C. Level 2B lymph node.
- D. Level 2A left neck dissection.
- E. Level 1 left neck dissection.
- F. Level 3 left neck dissection.
- G. Level 4 left neck dissection.
- H. Left lower mandibular tooth - gross only.
- I. Retromolar region, superior margin left
- J. Floor of mouth - FS.
- K. Inferior alveolar nerve -
- L. Mandible composite.

SPECIMEN DATA

GROSS DESCRIPTION:

- A. Part A received labeled and #1 buccal margin anterior to posterior is a 4.0 x 0.5 x 0.3 cm. irregular portion of tan-white mucosa. The anterior half is inked blue and the posterior black. The specimen is submitted in toto for frozen section and the frozen section residue is submitted in one cassette labeled
- B. Part B received labeled and #2 mental nerve is a 0.9 x 0.3 x 0.1 cm. irregular tan-white soft tissue which is submitted in toto for frozen section and the frozen section residue is submitted in one cassette labeled
- C. Part C received in formalin labeled and #3 level 2B lymph nodes is a 4.3 x 3.1 x 0.5 cm. irregular fibroadipose tissue. The specimen cannot be oriented. The specimen is sectioned to reveal multiple irregular tan-yellow firm tissues consistent with probable lymph node ranging from 0.2 x 0.2 x 0.1 cm. to 2.2 x 0.3 x 0.2 cm. Representative sections are submitted, to include the lymph nodes in their entirety as labeled: Blocks 1-3 three whole probable lymph nodes in each; Block 4—two whole probable lymph nodes. The blocks are labeled 1
- D. Part D received in formalin labeled and level 2A neck dissection left is a 3.8 x 2.7 x 0.6 cm. irregular fibroadipose tissue. The specimen cannot be oriented. The specimen is sectioned to reveal three irregular tan-yellow firm tissues consistent with possible lymph node ranging from 0.3 x 0.2 x 0.2 cm. to 2.1 x 0.6 x 0.3 cm. Representative sections are submitted to include the lymph nodes in their entirety as labeled: block 1—one whole possible lymph nodes; blocks 2 and 3—one lymph node, bisected in each. The blocks are labeled
- E. Part E received in formalin labeled and level 1 left neck dissection is a 7.1 x 5.4 x 1.7 cm. irregular portion of fibroadipose tissue and reddish-brown muscle. The specimen is sectioned to reveal a 4.8 x 3.7 x 1.1 cm. submandibular gland. The cut surface of the gland consists of lobulated tan-

[page 3 of 3]
SPECIMEN INFORMATION

yellow soft tissue. No lesions are identified. There are also multiple tan-red firm tissues consistent with probable lymph nodes ranging from 0.6 x 0.4 x 0.3 cm. to 2.4 x 0.8 x 0.7 cm. Representative sections are submitted to include the lymph nodes in their entirety as labeled: block 1—submandibular gland; blocks 2-4 one lymph node, bisected in each; blocks 5-7 one lymph node, serially sectioned. The blocks are labeled:

F. Part F is received in formalin labeled level 3 left neck dissection is a 6.4 x 2.8 x 0.8 cm. irregular fibroadipose tissue. The specimen cannot be oriented. The specimen is sectioned to reveal four tan-red firm tissues consistent with a probable lymph node ranging from 0.8 x 0.5 x 0.3 cm. to 2.9 x 1.4 x 0.6 cm. The specimen is sectioned and representative sections are submitted to include the lymph nodes in their entirety as labeled: blocks 1-3 one lymph node, bisected in each; blocks 4-6 one lymph node, trisected. The blocks are labeled:

G. Part G is received in formalin labeled level 4 left neck is a 6.3 x 3.5 x 0.9 cm. irregular fibroadipose tissue. The specimen cannot be oriented. The specimen is sectioned to reveal multiple tan-red firm tissues consistent with probable lymph node ranging from 0.3 x 0.2 cm. to 2.4 x 0.7 x 0.5 cm. Representative sections are submitted, to include the lymph nodes in their entirety as labeled: blocks 1 and 2—four whole probable lymph nodes; block 3—three whole probable lymph nodes; blocks 4-7 one lymph node, bisected in each; blocks 8-9 one lymph node, bisected. The blocks are labeled:

H. Part H is received in formalin labeled level 8 left lower mandibular tooth - gross only is a 1.8 x 0.6 x 0.4 cm. irregular hard tan yellow to white tooth. No soft tissue is present. No sections are submitted.

I. Part I received in formalin labeled level 9 left retromolar region superior margin is a 2.7 x 0.3 x 0.3 cm. irregular portion of gray-white mucosa. The medial half is inked black and the lateral blue. The specimen is submitted in toto for frozen section and the frozen section residue is submitted in one cassette labeled 1

J. Part J received labeled level 10 floor of mouth frozen section is a 4.3 x 0.3 x 0.2 cm. portion of gray-white mucosa. The specimen is inked, bisected and submitted in its entirety for frozen section. The frozen section residue is submitted in one cassette labeled

K. Part K received labeled level 11 inferior alveolar nerve is a 4.8 x 1.2 x 0.6 cm. irregular tan bone with attached 5.1 x 2.4 x 1.0 cm. portion of shaggy gray-white to tan-yellow soft tissue and muscle. The inferior alveolar nerve is inked yellow and the posterior mandible margin is inked blue. No lesions are identified within the soft tissue. There is a 0.7 x 0.3 cm. defect on the bone, 0.2 cm. from the margin. The proximal margin of the nerve is submitted en face for frozen section and the frozen section residue is submitted in block 1. Additional representative sections are submitted as labeled: blocks 2 and 3—soft tissue; block 4 bone margin to defect (perpendicular), following decalcification; block 5—remainder of bone margin entirely submitted (en face), following calcification. The blocks are labeled:

L. Part L received labeled level mandible composite is a partial mandibulectomy specimen consisting of a 4.9 x 1.7 x 1.5 cm. ramus, and a 4.4 x 3.2 x 1.8 cm. body. The specimen is partially surfaced by a 4.4 x 2.6 cm. portion of gray-white mucosa containing two teeth. The lateral half of the specimen is surfaced by a 5.6 x 5.5 x 2.7 cm. portion of shaggy tan-red soft tissue and muscle.

There is a 0.7 x 0.5 cm. defect in the posterior aspect of the mucosa, which is surrounded by granular tan-red tissue. This area is 0.5 cm., 1.0 cm., 2.7 cm., and 1.6 cm. from the lateral, medial, anterior, and posterior mucosal and soft tissue margins, respectively. The cut surface of the defect consists of a 3.9 x 2.5 x 1.8 cm. ill defined white lesion, 0.3 cm. from the anterior soft tissue margin. The lesion involves the bone and appears to extend to the outer surface of the ramus.

Both of the teeth have a silver metallic cap on the surface.

All margins are taken perpendicular. The specimen is inked, sectioned and representative sections are submitted as labeled: block 1—defect to lateral mucosa and soft tissue margins; block 2—medial mucosa and soft tissue margins; block 3—anterior mucosa and soft tissue margins; block 4—posterior mucosal and soft tissue margins; block 5—lesion to deep soft tissue margin; blocks 6 and 7—lesion to lateral soft tissue margin; block 8—lesion involving bone; block 9—body bone margin (en face), following decalcification; blocks 10 and 11 outer surface of ramus (en face), following decalcification. The blocks are labeled:

Also received in the same container is a green and yellow cassette labeled

for Genomic research study.

INTRA-OPERATIVE CONSULTATION:

A-B. FROZEN SECTION DIAGNOSIS: Negative per

I-J. FROZEN SECTION DIAGNOSIS: Negative per

K. FROZEN SECTION DIAGNOSIS: Negative per

Source: NCI Genomic Data Commons file 58e835b9-0a11-430b-8ddf-20ff78f399b6 (TCGA-HD-A633.E90995C6-3E59-4265-8D7F-4A5E94B946BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).